Somatic mutation profile of tumor specimen MBCProject_6113_T1_WES (aliquot MBCProject_6113_T1_WES_1) from CMI case MBCProject_6113, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 42.4 years (15,479 days).
Specimen MBCProject_6113_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 488c0728-9180-4eac-8105-e2e6834fd308.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_6113_SALIVA (Saliva), aliquot MBCProject_6113_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/822bce9e-70fa-45f9-8ce8-fe691d1a80bd

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 3, Silent 3, 3'UTR 2, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAIAP2 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs1382858567; called by muse, mutect2
- BORCS6 | c.1040G>T p.R347L | Missense Mutation (SNP) | VAF 32/498 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770798688; called by muse, mutect2
- C16orf96 | c.1349A>G p.Q450R | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.141); catalogued as rs900143331; called by muse, mutect2, varscan2
- CLMN | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 14/191 reads (7%) | catalogued as rs755257266; called by muse, mutect2
- FBXL6 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs374549929, COSV57352943; called by muse, mutect2, varscan2
- FER1L5 | c.2380G>A p.G794R (on ENST00000623019; = p.G799R on NM_001293083.2) | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1245987995; called by muse, mutect2
- LARP4B | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60224337; called by muse, mutect2
- NLRP7 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as rs748418867, COSV60180471; called by muse, mutect2
- PPP1R3F | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs782307066; called by muse, mutect2
- TBC1D14 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756133689; called by muse, mutect2
- VWF | c.6670G>A p.V2224M | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs1021756719, COSV54636575; called by muse, mutect2, varscan2
- BTN2A1 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 22/500 reads (4%) | called by muse, mutect2
- MCEMP1 | c.39G>C p.K13N | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); called by muse, mutect2
- PRUNE2 | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- SLC27A2 | c.1397T>G p.L466R | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CASR | c.1560C>A p.S520= (on ENST00000490131; = p.S597= on NM_000388.4) | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as COSV56140839; called by muse, mutect2
- STIM2 | c.702T>C p.A234= | Silent (SNP) | VAF 22/350 reads (6%) | catalogued as rs773719023; called by muse, mutect2
- SYN2 | c.405C>T p.V135= | Silent (SNP) | VAF 20/438 reads (5%) | called by muse, mutect2
- C2orf83 | n.278-1366G>A | Intron (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- CHST6 | c.*25C>T | 3'UTR (SNP) | VAF 11/194 reads (6%) | called by muse, mutect2
- NICN1 | c.*2315C>A | 3'UTR (SNP) | VAF 33/299 reads (11%) | called by muse, mutect2, varscan2
- TBC1D3P1 | n.699G>T | RNA (SNP) | VAF 42/1048 reads (4%) | called by muse, mutect2
- WDR59 | c.1713-40G>C | Intron (SNP) | VAF 18/179 reads (10%) | called by muse, mutect2, varscan2
- ZMYM6 | c.2147-1329T>G | Intron (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2
